Gene-level copy-number profile of tumor specimen TCGA-AG-3609-01A from TCGA case TCGA-AG-3609, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 65.5 years (23,925 days).
Specimen TCGA-AG-3609-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.c7b4764e-bb5d-4ef5-9c0a-979d95624a64.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3609-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48f18de6-5c22-46cd-ba7f-21568c073fc9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 6; copy number 2: 405; copy number 3: 79; copy number 4: 28,136; copy number 5: 7; copy number 6: 17,513; copy number 7: 77; copy number 8: 7,777; copy number 9: 735; copy number 10: 1,386; copy number 11: 994; copy number 12: 1,283; copy number 13: 753; copy number 15: 481; copy number 16: 9; copy number 17: 162.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AG-3609-01): tumor purity 0.67, ploidy 2.74, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:97,394,154–97,586,294, 3 genes: DPYD-IT1, SEC63P1, RPL26P9.
- chr3:11,272,309–11,557,665, 1 gene (within-gene range 0–4): ATG7.
- chr3:11,488,300–11,771,350, 5 genes (within-gene range 0–4): AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr4:91,108,023–91,112,790, 1 gene: AC004054.1.
- chr16:6,380,476–6,577,359, 2 genes: AC006112.1, AC007223.1.
- chr16:6,873,899–6,874,005, 1 gene: RNU6-457P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,393 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–154,155,116, 477 genes, copy number 12 (broad region; genes not listed).
- chr7:38,257,879–38,318,861, 9 genes, copy number 16: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr13:18,467,172–49,528,981, 616 genes, copy number 10–12 (within-gene range 7–12) (broad region; genes not listed).
- chr13:49,620,314–114,337,626, 774 genes, copy number 12 (broad region; genes not listed).
- chr18:20,946,906–21,241,371, 5 genes, copy number 9: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1.
- chr18:21,316,878–21,317,795, 1 gene, copy number 9: AC015878.2.
- chr18:31,447,741–35,145,417, 59 genes, copy number 9: DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1.
- chr20:87,250–16,053,197, 290 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr20:15,552,157–64,313,132, 1,162 genes, copy number 9–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
